Somatic mutation profile of tumor specimen 0DPAOH from CCDI case PBCDLD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.1 years (6,615 days).
Specimen 0DPAOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad49c4ea-d572-410b-ac11-661425d65810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPAOD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a62f226b-97f5-4cce-86f6-7ea2717ae8e6

The open-access MAF lists 267 somatic variants for this specimen: 158 protein-altering or splice-affecting, 68 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 68, Intron 30, Nonsense Mutation 11, 3'UTR 5, Splice Region 4, 5'UTR 3, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 216/305 reads (71%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- MSH6 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 360/636 reads (57%) | catalogued as rs63750909, CM042402, COSV52288483; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 526/923 reads (57%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, varscan2
- ACSM1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 300/508 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs751725508; called by muse, varscan2
- ADAT1 | c.238G>T p.G80* | Nonsense Mutation (SNP) | VAF 418/818 reads (51%) | catalogued as COSV57185397; called by muse, varscan2
- AICDA | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 366/1084 reads (34%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.999); catalogued as rs759799595, COSV57563513; called by muse, varscan2
- AMBRA1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 546/936 reads (58%) | catalogued as COSV54049679; called by muse, varscan2
- ARMH3 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 358/612 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs546798560; called by muse, varscan2
- BEGAIN | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 224/402 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1330669752; called by muse, varscan2
- C2orf68 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 354/605 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs760612952, COSV60473390; called by muse, varscan2
- CACNA1B | c.6979C>T p.R2327W | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765789569, COSV53142151; called by muse, varscan2
- CAMTA1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 230/422 reads (55%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.207); catalogued as rs866487669, COSV99079284; called by muse, varscan2
- CCDC114 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 246/411 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763939366, COSV59556469; ClinVar: uncertain significance; called by muse, varscan2
- CCDC127 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 731/1008 reads (73%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs955699186, COSV57256236; called by muse, varscan2
- CCDC168 | c.14887G>A p.E4963K | Missense Mutation (SNP) | VAF 299/503 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV59419112; called by muse, varscan2
- CCDC60 | c.1048T>A p.S350T | Missense Mutation (SNP) | VAF 330/1074 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV59543169; called by muse, varscan2
- CCHCR1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 320/554 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552884834; called by muse, varscan2
- CDH23 | c.9503G>A p.R3168H | Missense Mutation (SNP) | VAF 160/301 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754557923, COSV56468625; ClinVar: uncertain significance; called by muse, varscan2
- CFD | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 128/483 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs779126214; called by muse, varscan2
- CFH | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 291/488 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs377008918; called by muse, varscan2
- CHD5 | c.5139G>A p.T1713= | Splice Region (SNP) | VAF 522/826 reads (63%) | catalogued as rs1013767470; called by muse, varscan2
- CNTNAP5 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 391/679 reads (58%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.709); catalogued as rs201163242, COSV70513494; called by muse, varscan2
- CNTROB | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 254/458 reads (55%) | catalogued as rs780789745, COSV66607662; called by muse, varscan2
- CUBN | c.8593G>A p.V2865M | Missense Mutation (SNP) | VAF 346/614 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs146847375; called by muse, varscan2
- CYP2J2 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 272/452 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs144581123, COSV64606855; called by muse, varscan2
- DOCK6 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 354/584 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1344102335, COSV52949803; called by muse, varscan2
- DSCAML1 | c.3874G>A p.G1292R (on ENST00000321322; = p.G1232R on NM_020693.4) | Missense Mutation (SNP) | VAF 358/572 reads (63%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as rs200813659; called by muse, varscan2
- EPB41L3 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 200/336 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs749541572; called by muse, varscan2
- EPPK1 | c.5065G>A p.G1689S | Missense Mutation (SNP) | VAF 102/194 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554659803; called by muse, varscan2
- FAM160A1 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 184/288 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs907414867; called by muse, varscan2
- FAM186A | c.6010C>T p.R2004* | Nonsense Mutation (SNP) | VAF 312/942 reads (33%) | catalogued as rs566239340, COSV100524966; called by muse, varscan2
- FAT1 | c.5839C>T p.R1947C | Missense Mutation (SNP) | VAF 434/716 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751134485; called by muse, varscan2
- FGL2 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 456/854 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1447926721, COSV50380545; called by muse, varscan2
- FKRP | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 304/501 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs775201067, COSV59358220; called by muse, varscan2
- FSTL3 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 182/290 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs1160052605; called by muse, varscan2
- FZR1 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1568239317, COSV58051839; called by muse, varscan2
- GABRA6 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 208/456 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376700482, COSV50882721; called by muse, varscan2
- GPR141 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 276/828 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs139160883; called by muse, varscan2
- GPR45 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761119993, COSV51526096; called by muse, varscan2
- GUCY2F | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 378/654 reads (58%) | SIFT tolerated (1); PolyPhen possibly damaging (0.544); catalogued as COSV54299928; called by muse, varscan2
- HELQ | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 198/906 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs376881272; called by muse, varscan2
- IGF2R | c.5494C>T p.R1832C | Missense Mutation (SNP) | VAF 234/484 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); catalogued as rs757535144; called by muse, varscan2
- IL1RAP | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 220/1142 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs368426554; called by muse, varscan2
- ILDR1 | c.844G>A p.A282T (on ENST00000344209 / NM_001199799.2; = p.A238T on NM_175924.4) | Missense Mutation (SNP) | VAF 256/605 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1240134658; called by muse, varscan2
- INPP4A | c.2377C>T p.R793* (on ENST00000074304 / NM_001134224.1; = p.R754* on NM_001566.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 183/718 reads (25%) | catalogued as COSV50790458; called by muse, varscan2
- JCAD | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 182/332 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.1); catalogued as rs374312445, COSV64757723; called by muse, varscan2
- KAT14 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 268/446 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs777155707; called by muse, varscan2
- KLHL6 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 333/546 reads (61%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV58064706; called by muse, varscan2
- L3MBTL2 | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 51/511 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779700504; called by muse, varscan2
- LAMA1 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 274/492 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs776368738, COSV67541780; called by muse, varscan2
- LILRA4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 164/360 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs139101339; called by muse, varscan2
- LOXHD1 | c.4624G>A p.V1542M | Missense Mutation (SNP) | VAF 356/606 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1184461031, COSV100191479; called by muse, varscan2
- LRFN1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 186/308 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767921056, COSV50508017; called by muse, varscan2
- MAPK8IP1 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 144/250 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs564294379; called by muse, varscan2
- MELTF | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 285/537 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.04); catalogued as rs190096194, COSV56382588; called by muse, varscan2
- MEX3D | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 126/188 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs1378353879; called by muse, varscan2
- MKNK1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 306/560 reads (55%) | catalogued as rs146727868; called by muse, varscan2
- MNDA | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 559/998 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201766714; called by muse, varscan2
- MOV10L1 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 221/384 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs762620908, COSV53172621; called by muse, varscan2
- MRPS5 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 218/366 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs749418808, COSV55533559; called by muse, varscan2
- MYO1H | c.1503C>T p.T501= | Splice Region (SNP) | VAF 134/372 reads (36%) | catalogued as COSV100183834; called by muse, varscan2
- MYO3A | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 470/844 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs56403976, COSV56324596; called by muse, varscan2
- MYOM2 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 283/497 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316996365, COSV50707353; called by muse, varscan2
- NCAPD2 | c.4039C>T p.R1347C | Missense Mutation (SNP) | VAF 491/1464 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs373233854; called by muse, varscan2
- NCAPD3 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 334/540 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs867163348, COSV73258986; called by muse, varscan2
- NCOA6 | c.2525C>T p.S842L | Missense Mutation (SNP) | VAF 249/420 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1356016884; called by muse, varscan2
- NKAIN1 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 232/392 reads (59%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.742); catalogued as rs1252477033; called by muse, varscan2
- NLRP3 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 104/166 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs201377872, COSV100275557; called by muse, varscan2
- NOTCH1 | c.6898G>A p.G2300R | Missense Mutation (SNP) | VAF 188/316 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.415); catalogued as rs587778573, COSV99079433; ClinVar: uncertain significance / not provided; called by muse, varscan2
- NOTCH2 | c.4960G>A p.A1654T | Missense Mutation (SNP) | VAF 480/795 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs758689134, COSV104375144; called by muse, varscan2
- OTOGL | c.7046C>T p.T2349M (on ENST00000547103; = p.T2340M on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 292/720 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747031736, COSV54013827; called by muse, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 371/809 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, varscan2
- PDCD11 | c.3347C>T p.P1116L | Missense Mutation (SNP) | VAF 446/760 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs766219191; called by muse, varscan2
- PGF | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 144/268 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs201183034; called by muse, varscan2
- PIDD1 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 114/204 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs774798086; called by muse, varscan2
- PIWIL1 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 138/1182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755410536; called by muse, varscan2
- PLCH2 | c.3635G>A p.R1212Q | Missense Mutation (SNP) | VAF 112/198 reads (57%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs777108618; called by muse, varscan2
- PLCXD1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 358/648 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as rs371602769, COSV101087993; called by muse, varscan2
- PPP4R3A | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 416/706 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs750383941, COSV61506850; called by muse, varscan2
- PRICKLE2 | c.1789C>T p.R597W (on ENST00000295902; = p.R541W on NM_198859.4) | Missense Mutation (SNP) | VAF 292/471 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs372400638, COSV99897969; called by muse, varscan2
- PRKCH | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 204/345 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs760717622; called by muse, varscan2
- PRPF40B | c.826C>T p.R276W (on ENST00000380281; = p.R270W on NM_012272.3) | Missense Mutation (SNP) | VAF 216/646 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs147442665; called by muse, varscan2
- PRR11 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 378/704 reads (54%) | catalogued as rs747152495, COSV51878818; called by muse, varscan2
- PUM1 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 416/666 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1035388842, COSV57085105; called by muse, varscan2
- RET | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 208/363 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.143); catalogued as rs1427186016, COSV60710609; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- RFC5 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 443/1632 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs376942205; called by muse, varscan2
- RGSL1 | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 403/776 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs545939376; called by muse, varscan2
- RHOBTB1 | c.1391C>T p.T464M | Missense Mutation (SNP) | VAF 372/713 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs757070619, COSV61958251; called by muse, varscan2
- RNF17 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 286/502 reads (57%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.732); catalogued as rs1171024188; called by muse, varscan2
- RTP2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs569180222, COSV64078930; called by muse, varscan2
- SAMSN1 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 365/680 reads (54%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.779); catalogued as rs768377466; called by muse, varscan2
- SERINC3 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 190/768 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs778983913, COSV54855515; called by muse, varscan2
- SETD5 | c.3907G>A p.A1303T | Missense Mutation (SNP) | VAF 112/192 reads (58%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as rs377060727, COSV56717746; called by muse, varscan2
- SLAMF6 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 190/346 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747168600, COSV63586544; called by muse, varscan2
- SLC22A16 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 280/527 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs768435660, COSV57927384; called by muse, varscan2
- SLC2A4 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 186/356 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1448426414, COSV50300395; called by muse, varscan2
- SLC4A4 | c.2759T>C p.V920A (on ENST00000264485 / NM_001098484.3; = p.V876A on NM_003759.4) | Missense Mutation (SNP) | VAF 338/552 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1299649328; called by muse, varscan2
- SMARCAL1 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 318/538 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM020309, CM156531; called by muse, varscan2
- SMOC1 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 382/651 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs768727702; ClinVar: uncertain significance; called by muse, varscan2
- SPEG | c.9742C>T p.R3248C | Missense Mutation (SNP) | VAF 180/306 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs1357626784; called by muse, varscan2
- SPOCK2 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 178/280 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs988182177, COSV100436318; called by muse, varscan2
- SRPRA | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 334/592 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs148507841; called by muse, varscan2
- SSBP3 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 528/926 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62574518; called by muse, varscan2
- SSH3 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 95/174 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs773275703; called by muse, varscan2
- STAB1 | c.7438G>A p.V2480M | Missense Mutation (SNP) | VAF 192/312 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs199804726; called by muse, varscan2
- STX11 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62448453, COSV62450025; called by muse, varscan2
- SYNE2 | c.13742C>T p.A4581V | Missense Mutation (SNP) | VAF 503/831 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs769686910, COSV59969223; called by muse, varscan2
- TCF7 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 178/298 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs368119232; called by muse, varscan2
- TECPR2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 299/506 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs761797374; called by muse, varscan2
- THRAP3 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 372/644 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1330733410, COSV63568698, COSV63570182; called by muse, varscan2
- TMEM54 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 90/465 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs779851836, COSV61275983; called by muse, varscan2
- TNRC18 | c.5270C>T p.T1757M | Missense Mutation (SNP) | VAF 252/906 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); catalogued as rs142956093; called by muse, varscan2
- TRAF6 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 352/594 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs756987677, COSV61922712; called by muse, varscan2
- UHRF1 | c.752C>T p.T251M (on ENST00000612630 / NM_001290050.1; = p.T264M on NM_013282.4) | Missense Mutation (SNP) | VAF 202/340 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs377548045, COSV53576073; called by muse, varscan2
- UNC79 | c.4418C>T p.T1473M (on ENST00000393151 / NM_001346218.2; = p.T1296M on NM_020818.5) | Missense Mutation (SNP) | VAF 340/601 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); catalogued as rs756736233; called by muse, varscan2
- USP25 | c.2995C>T p.P999S | Missense Mutation (SNP) | VAF 238/378 reads (63%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1437709862; called by muse, varscan2
- VWF | c.7432C>T p.R2478W | Missense Mutation (SNP) | VAF 196/558 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs771694902, COSV54614623; called by muse, varscan2
- VWF | c.2233G>A p.G745R | Missense Mutation (SNP) | VAF 280/732 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs367811486; called by muse, varscan2
- ZBED2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 176/280 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs376107359; called by muse, varscan2
- ZFAT | c.3301G>A p.V1101I | Missense Mutation (SNP) | VAF 72/566 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs757186542, COSV64738202; called by muse, varscan2
- ZNF268 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 596/1844 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs377003792; called by muse, varscan2
- ZNF317 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 126/194 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV56109018; called by muse, varscan2
- ZNF541 | c.1921G>A p.G641S | Missense Mutation (SNP) | VAF 156/230 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs892227188; called by muse, varscan2
- ZNF606 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 294/562 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as rs762801474, COSV58706961; called by muse, varscan2
- ZNF646 | c.4072C>T p.R1358W | Missense Mutation (SNP) | VAF 227/438 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.549); catalogued as rs780599419; called by muse, varscan2
- ZNF835 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV73379803; called by muse, varscan2
- ZP4 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 502/885 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs139132490; called by muse, varscan2
- ANO8 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 122/245 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); called by muse, varscan2
- AP1M2 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 198/360 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- ASF1B | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.093); called by muse, varscan2
- B3GALT2 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 306/489 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- B3GNT4 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 286/762 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CXCL12 | c.82T>A p.Y28N | Missense Mutation (SNP) | VAF 276/436 reads (63%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); called by muse, varscan2
- GET4 | c.583T>C p.F195L | Missense Mutation (SNP) | VAF 234/666 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GLI3 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 264/792 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, varscan2
- GYG2 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 189/304 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.21); called by muse, varscan2
- HS3ST6 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.025); called by muse, varscan2
- KANK4 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- LRRC55 | c.64T>A p.S22T | Missense Mutation (SNP) | VAF 164/235 reads (70%) | SIFT tolerated (0.4); PolyPhen benign (0.133); called by muse, varscan2
- LRRK2 | c.2502T>C p.N834= | Splice Region (SNP) | VAF 372/1043 reads (36%) | called by muse, varscan2
- LTBP4 | c.4508G>A p.R1503Q (on ENST00000308370 / NM_001042544.1; = p.R1466Q on NM_003573.2) | Missense Mutation (SNP) | VAF 79/455 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, varscan2
- MATK | c.583-3C>T | Splice Region (SNP) | VAF 48/110 reads (44%) | called by muse, varscan2
- MAU2 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 198/340 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); called by muse, varscan2
- MGAM2 | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 572/1048 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- MUC22 | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 239/420 reads (57%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- NDUFA9 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 279/1048 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, varscan2
- OR1S2 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 382/665 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- RRH | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 433/763 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- SNCG | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 415/656 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- STYK1 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 230/790 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, varscan2
- SUOX | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TASP1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 581/918 reads (63%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.831); called by muse, varscan2
- USP5 | c.2274G>A p.W758* (on ENST00000229268 / NM_001098536.2; = p.W735* on NM_003481.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 282/720 reads (39%) | called by muse, varscan2
- USP8 | c.1646C>T p.T549I | Missense Mutation (SNP) | VAF 265/470 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, varscan2
- YLPM1 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 234/506 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.996); called by muse, varscan2
- ZMYM1 | c.100T>A p.Y34N | Missense Mutation (SNP) | VAF 82/472 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, varscan2
- ZNF460 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 210/382 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, varscan2
- ZNF629 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 123/209 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, varscan2
- ABCA13 | c.11964T>C p.I3988= | Silent (SNP) | VAF 210/735 reads (29%) | called by muse, varscan2
- ABCC10 | c.1617G>A p.T539= (on ENST00000372530 / NM_001198934.2; = p.T496= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 173/267 reads (65%) | catalogued as rs775232220, COSV55086287; called by muse, varscan2
- ACAP3 | c.1041C>T p.S347= | Silent (SNP) | VAF 130/254 reads (51%) | catalogued as rs771170360; called by muse, varscan2
- ADCY1 | c.1692C>T p.R564= | Silent (SNP) | VAF 400/1034 reads (39%) | catalogued as rs367735209; called by muse, varscan2
- AGPAT1 | c.153C>T p.L51= | Silent (SNP) | VAF 416/713 reads (58%) | catalogued as rs1477099013; called by muse, varscan2
- ANK1 | c.1650G>A p.R550= | Silent (SNP) | VAF 272/462 reads (59%) | called by muse, varscan2
- ANK2 | c.5757C>T p.S1919= | Silent (SNP) | VAF 664/1088 reads (61%) | catalogued as rs543514702, COSV52191748; called by muse, varscan2
- ARRDC5 | c.615C>T p.V205= (on ENST00000381781; = p.V191= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 156/260 reads (60%) | catalogued as rs201796717; called by muse, varscan2
- ATG2A | c.3807G>A p.S1269= | Silent (SNP) | VAF 135/234 reads (58%) | catalogued as rs139582510; called by muse, varscan2
- ATP2B1 | c.2619C>T p.G873= | Silent (SNP) | VAF 339/1004 reads (34%) | catalogued as rs775895156, COSV53806062; called by muse, varscan2
- B4GALNT3 | c.2613G>A p.P871= | Silent (SNP) | VAF 254/803 reads (32%) | catalogued as rs760374578, COSV56751923; called by muse, varscan2
- C7orf26 | c.972G>A p.P324= | Silent (SNP) | VAF 42/242 reads (17%) | called by muse, varscan2
- CCZ1 | c.771C>T p.I257= | Silent (SNP) | VAF 330/1206 reads (27%) | catalogued as rs754167679; called by muse, varscan2
- CDH23 | c.4095C>T p.D1365= | Silent (SNP) | VAF 212/455 reads (47%) | catalogued as rs368582818; ClinVar: likely benign; called by muse, varscan2
- CES3 | c.1245C>T p.D415= | Silent (SNP) | VAF 339/609 reads (56%) | catalogued as rs751744410, COSV57593914; called by muse, varscan2
- CHST1 | c.1098C>T p.Y366= | Silent (SNP) | VAF 122/220 reads (55%) | catalogued as rs1201538084, COSV57323001; called by muse, varscan2
- CRB1 | c.1575C>T p.F525= | Silent (SNP) | VAF 196/398 reads (49%) | catalogued as COSV66334393; called by muse, varscan2
- DCAF5 | c.1437C>T p.N479= | Silent (SNP) | VAF 100/155 reads (65%) | catalogued as rs758528270, COSV58461482; called by muse, varscan2
- DLGAP1 | c.1515C>T p.D505= | Silent (SNP) | VAF 66/466 reads (14%) | catalogued as rs369261142; called by muse, varscan2
- DNHD1 | c.4134C>T p.C1378= | Silent (SNP) | VAF 362/602 reads (60%) | catalogued as rs1187833790, COSV54440342; called by muse, varscan2
- DRD2 | c.540C>T p.N180= | Silent (SNP) | VAF 88/164 reads (54%) | catalogued as rs200496289, COSV60757439; called by muse, varscan2
- ERO1B | c.786C>T p.C262= | Silent (SNP) | VAF 358/654 reads (55%) | catalogued as rs143943782; called by muse, varscan2
- FGF17 | c.228C>T p.T76= | Silent (SNP) | VAF 214/316 reads (68%) | catalogued as rs202190340; called by muse, varscan2
- FOXQ1 | c.94C>T p.L32= | Silent (SNP) | VAF 38/249 reads (15%) | catalogued as rs747839954; called by muse, varscan2
- GOLGA3 | c.999G>A p.S333= | Silent (SNP) | VAF 57/195 reads (29%) | catalogued as rs750778392; called by muse, varscan2
- GRIN2C | c.1551C>T p.S517= | Silent (SNP) | VAF 212/452 reads (47%) | catalogued as rs201943001, COSV53115780, COSV99501041; called by muse, varscan2
- HAPLN4 | c.726C>T p.G242= | Silent (SNP) | VAF 250/410 reads (61%) | catalogued as rs1486560252, COSV99363917; called by muse, varscan2
- HECTD4 | c.8538C>T p.D2846= | Silent (SNP) | VAF 322/906 reads (36%) | called by muse, varscan2
- KLHL34 | c.126G>A p.A42= | Silent (SNP) | VAF 272/392 reads (69%) | called by muse, varscan2
- KSR2 | c.2604C>T p.H868= | Silent (SNP) | VAF 230/780 reads (29%) | catalogued as rs372963152; called by muse, varscan2
- LRRC14B | c.1302C>T p.A434= | Silent (SNP) | VAF 168/250 reads (67%) | catalogued as rs768233137; called by muse, varscan2
- MAG | c.1554C>T p.G518= | Silent (SNP) | VAF 110/210 reads (52%) | catalogued as rs200430942, COSV62699711; called by muse, varscan2
- MFSD5 | c.744C>T p.R248= | Silent (SNP) | VAF 138/446 reads (31%) | catalogued as rs938781390; called by muse, varscan2
- MMP19 | c.663G>A p.G221= | Silent (SNP) | VAF 36/296 reads (12%) | catalogued as rs1292507745; called by muse, varscan2
- MMRN2 | c.1977C>T p.A659= | Silent (SNP) | VAF 76/120 reads (63%) | called by muse, varscan2
- MUC5B | c.13116G>A p.T4372= | Silent (SNP) | VAF 196/324 reads (60%) | catalogued as rs746438655, COSV71590957; called by muse, varscan2
- NOTCH1 | c.3075C>T p.C1025= | Silent (SNP) | VAF 122/198 reads (62%) | catalogued as rs764208271, COSV99489496; called by muse, varscan2
- NRXN3 | c.471T>C p.V157= (on ENST00000557594 / NM_001272020.2; = p.V789= on NM_004796.6) | Silent (SNP) | VAF 84/454 reads (19%) | called by muse, varscan2
- NUMA1 | c.5502G>A p.S1834= | Silent (SNP) | VAF 186/344 reads (54%) | catalogued as rs763350835, COSV52620379; called by muse, varscan2
- OR5I1 | c.378C>T p.V126= | Silent (SNP) | VAF 273/427 reads (64%) | catalogued as rs750671530, COSV56889023; called by muse, varscan2
- PEG3 | c.93G>A p.P31= | Silent (SNP) | VAF 316/504 reads (63%) | catalogued as rs182961814, COSV55631349; called by muse, varscan2
- PEX19 | c.192C>T p.F64= | Silent (SNP) | VAF 468/774 reads (60%) | catalogued as rs750771594, COSV63619356; called by muse, varscan2
- PIF1 | c.1308C>T p.N436= | Silent (SNP) | VAF 256/511 reads (50%) | catalogued as rs752487060; called by muse, varscan2
- PIGG | c.372G>A p.T124= | Silent (SNP) | VAF 186/337 reads (55%) | catalogued as rs559827237, COSV56320496; ClinVar: uncertain significance; called by muse, varscan2
- PLEKHG4 | c.2280C>T p.P760= | Silent (SNP) | VAF 76/362 reads (21%) | catalogued as rs151308785; called by muse, varscan2
- PPM1H | c.453C>T p.D151= | Silent (SNP) | VAF 438/1363 reads (32%) | catalogued as COSV57374113; called by muse, varscan2
- PRRT3 | c.2853C>T p.T951= | Silent (SNP) | VAF 208/340 reads (61%) | called by muse, varscan2
- RASGRF1 | c.396C>T p.L132= | Silent (SNP) | VAF 170/385 reads (44%) | catalogued as rs774843151, COSV69177849; called by muse, varscan2
- RBM12B | c.2322G>A p.P774= | Silent (SNP) | VAF 248/360 reads (69%) | catalogued as rs763011271; called by muse, varscan2
- RBM19 | c.2391C>T p.H797= | Silent (SNP) | VAF 139/451 reads (31%) | catalogued as rs769404750, COSV55697923; called by muse, varscan2
- RTN4RL1 | c.615C>T p.H205= | Silent (SNP) | VAF 176/326 reads (54%) | catalogued as rs756699810, COSV58674834; called by muse, varscan2
- SCN9A | c.1680A>G p.R560= | Silent (SNP) | VAF 400/802 reads (50%) | called by muse, varscan2
- SLC7A3 | c.543C>T p.L181= | Silent (SNP) | VAF 228/416 reads (55%) | catalogued as rs914366791; called by muse, varscan2
- SMARCD1 | c.831C>T p.D277= | Silent (SNP) | VAF 588/1669 reads (35%) | catalogued as rs1050727, COSV67412204; called by muse, varscan2
- SPATA20 | c.2058G>A p.A686= (on ENST00000356488 / NM_001258372.1; = p.A702= on NM_022827.4) | Silent (SNP) | VAF 506/816 reads (62%) | catalogued as rs756310343, COSV50068218, COSV50069167; called by muse, varscan2
- SPTLC3 | c.162G>A p.S54= | Silent (SNP) | VAF 413/671 reads (62%) | catalogued as rs189860206, COSV100983036; called by muse, varscan2
- STAB1 | c.7563C>T p.D2521= | Silent (SNP) | VAF 178/302 reads (59%) | catalogued as rs147274795; called by muse, varscan2
- SYNPO2L | c.606G>A p.P202= | Silent (SNP) | VAF 76/136 reads (56%) | catalogued as rs746846008; called by muse, varscan2
- TCF20 | c.3642G>A p.P1214= | Silent (SNP) | VAF 120/208 reads (58%) | catalogued as rs367613861, COSV100166419; called by muse, varscan2
- TERT | c.1695G>A p.E565= | Silent (SNP) | VAF 470/1362 reads (35%) | catalogued as COSV57243900; called by muse, varscan2
- TMEM35A | c.297G>A p.L99= | Silent (SNP) | VAF 185/747 reads (25%) | called by muse, varscan2
- TRIM2 | c.1119C>T p.D373= (on ENST00000437508; = p.D400= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 384/802 reads (48%) | catalogued as rs367607996; called by muse, varscan2
- TRMT2A | c.1515C>T p.L505= | Silent (SNP) | VAF 270/518 reads (52%) | catalogued as rs762744801, COSV52812359; called by muse, varscan2
- TSPYL5 | c.588A>G p.P196= | Silent (SNP) | VAF 238/378 reads (63%) | called by muse, varscan2
- TTC39B | c.1518C>T p.A506= | Silent (SNP) | VAF 396/726 reads (55%) | catalogued as rs758339076, COSV52613899, COSV99895917; called by muse, varscan2
- USP41 | c.6C>T p.D2= | Silent (SNP) | VAF 272/441 reads (62%) | catalogued as rs1372626402; called by muse, varscan2
- ZNF414 | c.624G>A p.P208= | Silent (SNP) | VAF 154/293 reads (53%) | called by muse, varscan2
- ZNF696 | c.201G>A p.A67= | Silent (SNP) | VAF 197/314 reads (63%) | catalogued as COSV100350465; called by muse, varscan2
- ABCF1 | c.1242+14C>T | Intron (SNP) | VAF 292/552 reads (53%) | catalogued as rs376867724; called by muse, varscan2
- APOBEC3F | c.451+33G>A | Intron (SNP) | VAF 68/124 reads (55%) | catalogued as rs538464630; called by muse, varscan2
- ARPC1B | c.500+13G>A | Intron (SNP) | VAF 142/218 reads (65%) | catalogued as rs371784878; called by muse, varscan2
- ASL | c.446+84C>T | Intron (SNP) | VAF 18/24 reads (75%) | catalogued as rs1300340487; called by muse, varscan2
- ATG4D | c.319+43C>T | Intron (SNP) | VAF 88/164 reads (54%) | catalogued as rs371425272; called by muse, varscan2
- C2CD6 | c.1582-3783A>T | Intron (SNP) | VAF 282/985 reads (29%) | called by muse, varscan2
- C3orf70 | c.-57A>G | 5'UTR (SNP) | VAF 51/75 reads (68%) | called by muse, varscan2
- CCHCR1 | c.698+10C>T | Intron (SNP) | VAF 172/286 reads (60%) | catalogued as rs762416029; called by muse, varscan2
- CCNT1 | c.706+65G>T | Intron (SNP) | VAF 125/324 reads (39%) | called by muse, varscan2
- CD68 | chr17:7583010 G>A | 3'Flank (SNP) | VAF 258/395 reads (65%) | called by muse, varscan2
- CD81 | c.*92G>A | 3'UTR (SNP) | VAF 30/54 reads (56%) | catalogued as rs1183219183; called by muse, varscan2
- CDC123 | c.846+21A>G | Intron (SNP) | VAF 262/490 reads (53%) | catalogued as rs1327413084; called by muse, varscan2
- COBL | c.1096+2108C>T | Intron (SNP) | VAF 222/653 reads (34%) | catalogued as rs540915260; called by muse, varscan2
- COL6A2 | c.*5G>A | 3'UTR (SNP) | VAF 162/312 reads (52%) | catalogued as rs377195134, CR161896; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, varscan2
- COL7A1 | c.8819-48C>T | Intron (SNP) | VAF 71/103 reads (69%) | catalogued as rs750993855; called by muse, varscan2
- COLEC11 | c.-7G>A | 5'UTR (SNP) | VAF 196/336 reads (58%) | catalogued as rs754379537, COSV52598936; called by muse, varscan2
- CORO7 | c.2340+27C>T | Intron (SNP) | VAF 56/104 reads (54%) | catalogued as rs758741547; called by muse, varscan2
- CYB5R2 | c.-61G>A | 5'UTR (SNP) | VAF 42/72 reads (58%) | catalogued as rs757545414; called by muse, varscan2
- DCST2 | c.806-93G>A | Intron (SNP) | VAF 18/29 reads (62%) | catalogued as rs539486841; called by muse, varscan2
- ERVV-2 | c.*3C>G | 3'UTR (SNP) | VAF 96/154 reads (62%) | called by muse, varscan2
- FAM193A | c.1026+20G>A | Intron (SNP) | VAF 238/399 reads (60%) | catalogued as rs992189260; called by muse, varscan2
- GRHL1 | c.1110+21G>A | Intron (SNP) | VAF 248/362 reads (69%) | catalogued as rs1276186532; called by muse, varscan2
- IL16 | chr15:81313458 G>A | 3'Flank (SNP) | VAF 160/250 reads (64%) | called by muse, varscan2
- LETM2 | c.783+44G>A | Intron (SNP) | VAF 82/123 reads (67%) | catalogued as rs750609207; called by muse, varscan2
- LIG1 | c.2385+24G>A | Intron (SNP) | VAF 94/403 reads (23%) | called by muse, varscan2
- LSM4 | c.144+21C>T | Intron (SNP) | VAF 75/159 reads (47%) | catalogued as rs199866051; called by muse, varscan2
- MDH2 | c.429+72C>T | Intron (SNP) | VAF 53/82 reads (65%) | catalogued as rs911995858; called by muse, varscan2
- MUCL3 | c.947-59G>T | Intron (SNP) | VAF 294/514 reads (57%) | catalogued as COSV58517639; called by muse, varscan2
- MYO1G | c.1503+9G>A | Intron (SNP) | VAF 210/502 reads (42%) | catalogued as rs772059244; called by muse, varscan2
- NKTR | c.1018-37G>T | Intron (SNP) | VAF 69/274 reads (25%) | called by muse, varscan2
- NOMO2 | c.1806+37C>T | Intron (SNP) | VAF 93/182 reads (51%) | catalogued as rs527753341; called by muse, varscan2
- PDE4A | c.*1304G>C | 3'UTR (SNP) | VAF 13/54 reads (24%) | catalogued as rs1276975462; called by muse, varscan2
- PHGDH | c.290+23G>A | Intron (SNP) | VAF 98/361 reads (27%) | catalogued as rs769225173; called by muse, varscan2
- PLSCR3 | c.287-38G>A | Intron (SNP) | VAF 169/316 reads (53%) | catalogued as rs1013134098; called by muse, varscan2
- RNU1-153P | chr1:145165075 C>T | 5'Flank (SNP) | VAF 153/782 reads (20%) | catalogued as rs1204548314; called by muse, varscan2
- SETD3 | c.735-41T>C | Intron (SNP) | VAF 28/104 reads (27%) | called by muse, varscan2
- TATDN2 | c.*9+33G>A | Intron (SNP) | VAF 146/310 reads (47%) | catalogued as rs1032090915; called by muse, varscan2
- TBC1D10C | c.649-32C>T | Intron (SNP) | VAF 124/206 reads (60%) | catalogued as rs927570576; called by muse, varscan2
- TMEM255B | c.423+48G>A | Intron (SNP) | VAF 58/83 reads (70%) | catalogued as rs755373819; called by muse, varscan2
- VAMP1 | c.341-92C>T | Intron (SNP) | VAF 24/66 reads (36%) | catalogued as rs888238380; called by muse, varscan2
- YLPM1 | c.*16C>T | 3'UTR (SNP) | VAF 142/216 reads (66%) | catalogued as rs537457746; called by muse, varscan2
